Somatic mutation profile of tumor specimen TCGA-E7-A4XJ-01A (aliquot TCGA-E7-A4XJ-01A-11D-A26M-08) from TCGA case TCGA-E7-A4XJ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 66.5 years (24,279 days).
Specimen TCGA-E7-A4XJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e9b7a76-13c8-426e-af46-2bb315f0261b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E7-A4XJ-10A (Blood Derived Normal), aliquot TCGA-E7-A4XJ-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5f783bfc-a741-4fdd-8297-e069d990e431

The open-access MAF lists 46 somatic variants for this specimen: 34 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 26, Silent 12, Nonsense Mutation 3, Frame Shift Ins 2, Frame Shift Del 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA5 | c.2532G>A p.M844I | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV67016922; called by muse, mutect2, varscan2
- ADGRL4 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs764619199, COSV66059595; called by muse, mutect2
- ANKS1A | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762871214, COSV64460780; called by muse, mutect2, varscan2
- ANO5 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs200265848, COSV61081891, COSV61082106; called by muse, mutect2, varscan2
- ARID1A | c.1669C>T p.Q557* | Nonsense Mutation (SNP) | VAF 103/303 reads (34%) | catalogued as COSV61377632; called by muse, mutect2, varscan2
- BRAF | c.1900G>T p.D634Y (on ENST00000288602 / NM_001374244.1; = p.D594Y on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV56061673, COSV56106240, COSV56184663; called by muse, mutect2, varscan2
- CHSY1 | c.611C>T p.T204M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.432); catalogued as rs573785211, COSV54253371; called by muse, mutect2, varscan2
- CNNM4 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 132/310 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV65660920; called by muse, mutect2, varscan2
- CNTNAP1 | c.900G>A p.E300= | Splice Region (SNP) | VAF 45/115 reads (39%) | catalogued as COSV52850636; called by muse, mutect2, varscan2
- DMD | c.8641C>G p.L2881V | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as CD093453, COSV100627977; called by muse, mutect2, varscan2
- DNAH5 | c.11128C>T p.R3710C | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs750661309, COSV54225374; called by muse, mutect2, varscan2
- EPHA3 | c.2798C>T p.T933M | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.91); catalogued as rs372594677; called by muse, varscan2
- FLNB | c.109A>G p.I37V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.144); catalogued as rs1249133663, COSV55879695; called by muse, mutect2, varscan2
- GRM4 | c.2036G>A p.R679H | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1562013185, COSV65211150; called by muse, mutect2, varscan2
- HMCN1 | c.9638G>A p.R3213Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1173159547, COSV54901168; called by muse, mutect2, varscan2
- IGF1R | c.2089G>A p.G697R | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.612); catalogued as COSV51288348; called by muse, mutect2, varscan2
- KCNN2 | c.1448C>A p.A483E (on ENST00000264773; = p.A695E on NM_021614.4) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV53288766; called by muse, mutect2, varscan2
- MYCBP2 | c.2164A>C p.K722Q (on ENST00000357337; = p.K760Q on NM_015057.5) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.702); catalogued as COSV62019675; called by muse, mutect2, varscan2
- NFASC | c.1576C>T p.R526W (on ENST00000339876 / NM_001378329.1; = p.R537W on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs377722677; called by muse, mutect2, varscan2
- OR5T3 | c.842A>G p.D281G | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as COSV57380665; called by muse, mutect2, varscan2
- PTPN1 | c.872G>A p.W291* | Nonsense Mutation (SNP) | VAF 44/109 reads (40%) | catalogued as COSV100860586; called by muse, mutect2, varscan2
- RAB10 | c.11A>C p.K4T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV53089866; called by muse, mutect2, varscan2
- RANBP2 | c.4663C>T p.R1555* | Nonsense Mutation (SNP) | VAF 45/106 reads (42%) | catalogued as COSV51696089; called by muse, mutect2, varscan2
- RGS7 | c.433C>G p.L145V | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58542199; called by muse, mutect2, varscan2
- RIMS1 | c.1495G>C p.D499H | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as COSV99327915; called by mutect2, varscan2
- SLC25A17 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.092); catalogued as COSV99610689; called by muse, mutect2
- TCIRG1 | c.977T>A p.V326E | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV55835557; called by muse, varscan2
- VPS13B | c.4325C>T p.T1442I | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV62142229; called by muse, mutect2, varscan2
- ARID1A | c.3726_3727del p.S1242Rfs*16 | Frame Shift Del (DEL) | VAF 29/67 reads (43%) | called by mutect2, pindel, varscan2
- ATM | c.6940_6951del p.Q2314_K2317del | In Frame Del (DEL) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- IKZF3 | c.150_151insCT p.E51Lfs*4 | Frame Shift Ins (INS) | VAF 13/49 reads (27%) | called by mutect2, pindel, varscan2
- NRIP2 | c.112_113dup p.P39Hfs*14 | Frame Shift Ins (INS) | VAF 22/80 reads (28%) | called by mutect2, pindel, varscan2
- TAF15 | c.1129A>G p.N377D (on ENST00000605844 / NM_139215.3; = p.N374D on NM_003487.4) | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL13A1 | c.1506C>T p.R502= (on ENST00000398978 / NM_001130103.2; = p.R445= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs754892079, COSV62568712; ClinVar: likely benign; called by muse, mutect2, varscan2
- IDI1 | c.354C>G p.T118= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV101191310, COSV67281662; called by muse, mutect2, varscan2
- KCNIP4 | c.144G>T p.T48= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs368526954, COSV62850148; called by muse, varscan2
- LETMD1 | c.816G>A p.L272= | Silent (SNP) | VAF 39/95 reads (41%) | catalogued as COSV50396709; called by muse, mutect2, varscan2
- LIPF | c.510C>T p.G170= | Silent (SNP) | VAF 73/182 reads (40%) | catalogued as rs962630698, COSV53283766; called by muse, mutect2, varscan2
- MEGF10 | c.2703C>T p.V901= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as rs758284831, COSV57249271; called by muse, mutect2, varscan2
- NRXN3 | c.1818C>A p.S606= (on ENST00000557594 / NM_001272020.2; = p.S1030= on NM_004796.6) | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV55328392, COSV55332869; called by muse, mutect2, varscan2
- PGM2 | c.195T>A p.A65= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV67938785; called by muse, mutect2, varscan2
- ROBO1 | c.2988G>A p.T996= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs756175842, COSV71394132; called by muse, mutect2, varscan2
- SBNO2 | c.2499C>T p.R833= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs1021725248, COSV62320682; called by muse, mutect2, varscan2
- UBR4 | c.1692C>T p.T564= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs775370770, COSV64389870; called by muse, mutect2, varscan2
- VIRMA | c.4425C>T p.D1475= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV52585165; called by muse, mutect2, varscan2
